Somatic mutation profile of tumor specimen TCGA-55-1594-01A (aliquot TCGA-55-1594-01A-01D-1040-01) from TCGA case TCGA-55-1594, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-55-1594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e50ab05-e910-4dfe-b17d-b1e123539c2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1594-11A (Solid Tissue Normal), aliquot TCGA-55-1594-11A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9039f4ee-9316-4c52-bbff-e50b2354adfe

The open-access MAF lists 166 somatic variants for this specimen: 119 protein-altering or splice-affecting, 46 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 46, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 70/121 reads (58%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52211567; called by muse, mutect2, varscan2
- ADARB1 | c.2054C>T p.S685F (on ENST00000360697 / NM_001346687.2; = p.S645F on NM_001112.4) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV62348008; called by muse, mutect2, varscan2
- ADGRA1 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs764482205, COSV63416460, COSV63416660; called by muse, mutect2, varscan2
- ADGRA2 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59447127; called by muse, mutect2, varscan2
- AGAP4 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1347036003; called by mutect2, varscan2
- AQP12B | c.256C>A p.L86M (on ENST00000621682; = p.L98M on NM_001102467.2) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV68184462; called by muse, mutect2, varscan2
- ATMIN | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55147562; called by muse, mutect2, varscan2
- C9orf131 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV56614041; called by muse, mutect2, varscan2
- CCDC158 | c.3044C>G p.S1015C | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66357157; called by muse, mutect2, varscan2
- CCDC39 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56493284; called by muse, mutect2
- CCT8L2 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.308); catalogued as COSV63463644, COSV63463760; called by muse, mutect2, varscan2
- CDKN2A | c.300_301insT p.G101Wfs*19 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | catalogued as COSV58697242; called by mutect2, varscan2
- CDKN2A | c.298dup p.A100Gfs*20 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as CI119690; called by mutect2*, pindel, varscan2*
- CEP152 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as rs945108502, COSV57864597; called by muse, mutect2, varscan2
- CEP57 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57690358; called by muse, mutect2, varscan2
- CHCHD6 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs780164576, COSV52068738; called by muse, mutect2, varscan2
- CLCA4 | c.2322G>C p.W774C | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218044991, COSV65285115; called by muse, mutect2, varscan2
- CLK1 | c.1141-1G>T p.X381_splice | Splice Site (SNP) | VAF 28/191 reads (15%) | catalogued as COSV58433599; called by muse, mutect2, varscan2
- CMYA5 | c.11164A>G p.T3722A | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV71409343; called by muse, mutect2, varscan2
- COL11A1 | c.4225C>T p.L1409F | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1435827751, COSV62178944, COSV62196590; called by muse, mutect2, varscan2
- DCAF1 | c.4443G>T p.E1481D | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); catalogued as COSV60046466; called by muse, mutect2, varscan2
- DCST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs769529661, COSV55063085; called by muse, mutect2, varscan2
- DDX42 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV63791344; called by muse, mutect2, varscan2
- DNAI2 | c.799T>G p.Y267D | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV56762346; called by muse, mutect2, varscan2
- EBF3 | c.1072C>T p.Q358* (on ENST00000355311 / NM_001375392.1; = p.Q349* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 66/289 reads (23%) | catalogued as COSV62478994; called by muse, mutect2, varscan2
- EGFLAM | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs267600618, COSV59316379; called by muse, mutect2, varscan2
- EMSY | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1015568567, COSV58265540; called by muse, mutect2, varscan2
- EXPH5 | c.5773G>A p.D1925N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV56207960; called by muse, mutect2, varscan2
- FAM184A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58858621; called by muse, mutect2, varscan2
- FAM47B | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs778028004, COSV61453478; called by muse, mutect2, varscan2
- FBN2 | c.8140G>T p.E2714* | Nonsense Mutation (SNP) | VAF 84/182 reads (46%) | catalogued as COSV52544134; called by muse, mutect2, varscan2
- FBXO46 | c.567C>G p.S189R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1391428149, COSV58349666; called by muse, mutect2
- FGF9 | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as COSV66645707; called by muse, mutect2, varscan2
- FMO3 | c.1062A>C p.K354N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63008522; called by muse, mutect2, varscan2
- FSHR | c.433del p.Q145Kfs*11 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | catalogued as COSV100436354; called by mutect2, pindel, varscan2
- FYB2 | c.1201del p.E401Nfs*10 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | catalogued as COSV58588452; called by mutect2, pindel, varscan2
- GADL1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs751396281, COSV56985424; called by muse, mutect2, varscan2
- GOLGA1 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1396660217, COSV65230986; called by muse, mutect2, varscan2
- GOLM1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV57415999; called by muse, mutect2, varscan2
- GPR152 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56888052; called by muse, mutect2, varscan2
- HERC1 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71250117; called by muse, varscan2
- HNRNPC | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); catalogued as COSV60146135; called by muse, mutect2, varscan2
- HSDL2 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52717196; called by muse, mutect2, varscan2
- IFNL3 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69830193; called by muse, mutect2, varscan2
- INTS2 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV52156454; called by muse, mutect2, varscan2
- ITPR3 | c.1181C>A p.T394N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65412004; called by muse, mutect2, varscan2
- JADE3 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1556373000, COSV54470132; called by muse, mutect2, varscan2
- KCNH7 | c.2578G>C p.E860Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59812819; called by muse, mutect2, varscan2
- KCNK18 | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57973169; called by muse, mutect2, varscan2
- KLHL25 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61996461; called by muse, mutect2, varscan2
- KLK14 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50071089; called by muse, mutect2, varscan2
- KPRP | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100908697, COSV64222956; called by muse, mutect2, varscan2
- KRT74 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59773566; called by muse, mutect2, varscan2
- LATS2 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV66879628; called by muse, mutect2, varscan2
- LDHC | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55005949; called by muse, mutect2, varscan2
- LGI1 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65059205; called by muse, mutect2, varscan2
- LHX8 | c.409T>G p.S137A | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53959989; called by muse, mutect2, varscan2
- LTBP3 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV57242184, COSV57243724; called by muse, mutect2, varscan2
- LUZP2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61218258; called by muse, varscan2
- MANF | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56548689; called by muse, mutect2, varscan2
- MARCO | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59058404; called by muse, mutect2, varscan2
- MARF1 | c.3617+1G>T p.X1206_splice | Splice Site (SNP) | VAF 33/90 reads (37%) | catalogued as COSV60028819; called by muse, mutect2, varscan2
- MN1 | c.3338C>T p.S1113L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56555821; called by muse, varscan2
- MROH7 | c.3746G>A p.R1249K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV64888250; called by muse, mutect2, varscan2
- MS4A15 | c.668C>T p.A223V (on ENST00000405633 / NM_001098835.2; = p.A130V on NM_152717.3) | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV61961830; called by mutect2, varscan2
- MYO7A | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV68686959; called by muse, varscan2
- OCA2 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62357436; called by muse, mutect2, varscan2
- OCA2 | c.1549T>A p.C517S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV62357446; called by muse, mutect2, varscan2
- OR4C11 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs753199652, COSV56354938; called by muse, mutect2, varscan2
- OR51Q1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as COSV56180547; called by muse, mutect2, varscan2
- OR56A3 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61569997; called by muse, mutect2, varscan2
- PCDHB1 | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60633204; called by muse, mutect2, varscan2
- PCDHB7 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50813128; called by muse, mutect2, varscan2
- PCOLCE2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.796); catalogued as COSV56002004; called by muse, varscan2
- PCSK4 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV56298398; called by muse, mutect2, varscan2
- PI15 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99478142; called by muse, mutect2, varscan2
- PIGG | c.1543G>C p.A515P (on ENST00000453061 / NM_001127178.3; = p.A507P on NM_017733.4) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV56321351; called by muse, mutect2, varscan2
- PIGM | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63636053; called by muse, mutect2, varscan2
- PIK3R3 | c.1138T>C p.F380L | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53111057; called by muse, mutect2, varscan2
- POLR1A | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772030966, COSV55699465; called by muse, mutect2, varscan2
- RECK | c.1994A>T p.Q665L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65036291; called by muse, mutect2, varscan2
- RIN3 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as COSV53652630; called by muse, mutect2, varscan2
- RMND5B | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1561637151, COSV57746099; called by muse, mutect2, varscan2
- RPN2 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV52908850; called by muse, varscan2
- RPP25 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV100446257, COSV59120399; called by muse, mutect2, varscan2
- RYR2 | c.14841G>T p.R4947S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1252294768, COSV63690632, COSV63712252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAP30BP | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53130224; called by muse, mutect2, varscan2
- SEZ6L | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50685246; called by muse, mutect2, varscan2
- SH2B1 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV59466717; called by muse, mutect2, varscan2
- SLC22A4 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52360162; called by muse, mutect2, varscan2
- SLC27A1 | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53100677; called by muse, mutect2, varscan2
- SLC32A1 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV54148324; called by muse, mutect2, varscan2
- SLC5A7 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50902901; called by muse, mutect2, varscan2
- SLC6A16 | c.911T>G p.I304S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60030298; called by muse, mutect2, varscan2
- SORCS1 | c.1892T>G p.F631C | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53903433; called by muse, mutect2, varscan2
- SPDYC | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs372669084, COSV65865129; called by muse, mutect2, varscan2
- SRGAP1 | c.2533T>A p.L845I | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61903296; called by muse, mutect2, varscan2
- SRSF11 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63938356, COSV63939551; called by muse, mutect2, varscan2
- TANK | c.88T>A p.L30I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV52047727; called by muse, mutect2
- TEX33 | c.723T>A p.H241Q (on ENST00000381821 / NM_001163857.2; = p.H156Q on NM_178552.4) | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67822920; called by muse, mutect2, varscan2
- TM4SF19 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56557608; called by muse, mutect2, varscan2
- TNN | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs367714075, COSV53434983; called by muse, mutect2, varscan2
- TRPC3 | c.1858G>T p.V620L (on ENST00000379645 / NM_001366479.2; = p.V547L on NM_003305.2) | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53380965; called by muse, mutect2, varscan2
- TSPAN3 | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51216068; called by muse, mutect2, varscan2
- UNC13C | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1255994307, COSV52886584, COSV52913750; called by muse, mutect2, varscan2
- VCP | c.1937C>A p.P646Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62722136; called by muse, mutect2, varscan2
- WDR70 | c.1754C>G p.S585C | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54283317; called by muse, mutect2, varscan2
- ZMYM2 | c.2100G>C p.K700N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs535395618, COSV67037454; called by muse, mutect2, varscan2
- ZNF141 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53661643; called by muse, mutect2, varscan2
- ZNF160 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV62000907, COSV62001388; called by muse, mutect2, varscan2
- ZNF283 | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61032956; called by mutect2, varscan2
- ZNF566 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV67574730; called by muse, mutect2, varscan2
- ZNF611 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.454); catalogued as COSV60543263; called by muse, mutect2, varscan2
- ZNF638 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV52496581; called by muse, varscan2
- ZNF70 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 56/276 reads (20%) | catalogued as COSV59533799; called by muse, mutect2, varscan2
- ABCC1 | c.2290_2292del p.K764del | In Frame Del (DEL) | VAF 24/221 reads (11%) | called by mutect2, pindel, varscan2
- EIF5B | c.1840_1842+4del p.X614_splice | Splice Site (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- TAS2R31 | c.28dup p.S10Ffs*15 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | called by pindel, varscan2
- AOX1 | c.720A>G p.R240= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs908276524, COSV65983868; called by muse, mutect2, varscan2
- ATP6V1A | c.666A>C p.P222= | Silent (SNP) | VAF 49/310 reads (16%) | catalogued as COSV56364560; called by muse, mutect2, varscan2
- CABLES2 | c.411C>G p.A137= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54158362; called by muse, mutect2, varscan2
- CLSTN2 | c.201C>T p.A67= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as rs1294909541, COSV71724865; called by muse, mutect2
- CTBP2 | c.648G>T p.G216= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV58337852; called by muse, mutect2, varscan2
- DGLUCY | c.1785G>T p.L595= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV56366072; called by muse, mutect2, varscan2
- DLL4 | c.375A>T p.P125= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs751229569, COSV51071223; called by muse, mutect2, varscan2
- FLNA | c.1872C>T p.D624= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as rs1557178770, COSV61041102; ClinVar: likely benign; called by muse, varscan2
- FSIP2 | c.20118G>C p.T6706= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as rs779866454, COSV58090474, COSV58100545; called by muse, mutect2, varscan2
- GALNT11 | c.1773C>T p.V591= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs368113531; called by muse, mutect2, varscan2
- GAS2L1 | c.405C>T p.S135= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV53329937; called by muse, mutect2
- ID3 | c.156G>A p.R52= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as COSV65801486; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1098A>T p.A366= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV67348087; called by muse, mutect2, varscan2
- LIG3 | c.2616G>A p.K872= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV99252911; called by muse, mutect2
- LRCH4 | c.420C>A p.V140= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV53829269; called by muse, varscan2
- LZTS1 | c.156C>T p.H52= | Silent (SNP) | VAF 77/156 reads (49%) | catalogued as rs745621744, COSV56117136; called by muse, mutect2, varscan2
- MAN1A2 | c.366A>C p.A122= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV62981474; called by muse, mutect2, varscan2
- MORC1 | c.1131C>T p.I377= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs144305402, COSV51725258; called by muse, mutect2, varscan2
- MSH2 | c.2673G>C p.V891= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV51884709; called by muse, mutect2, varscan2
- MYO7B | c.2796G>A p.Q932= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1156874045, COSV67351715; called by muse, mutect2, varscan2
- NFASC | c.2046C>A p.P682= (on ENST00000339876 / NM_001378329.1; = p.P678= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/276 reads (17%) | catalogued as COSV58361844, COSV58379379; called by muse, mutect2, varscan2
- NFXL1 | c.1540A>C p.R514= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61200704; called by muse, mutect2, varscan2
- NSUN6 | c.171G>A p.V57= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs369325065; called by muse, mutect2, varscan2
- PARP11 | c.246C>T p.F82= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV57393794; called by muse, mutect2, varscan2
- PCDH17 | c.1863G>T p.G621= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV64978920; called by muse, mutect2
- PCDHB4 | c.1740G>A p.E580= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV52026763; called by muse, mutect2, varscan2
- PI15 | c.324C>T p.C108= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV52641257, COSV52641429; called by muse, mutect2, varscan2
- PLCB3 | c.2022C>T p.L674= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV54191818, COSV54192248; called by muse, mutect2, varscan2
- PMEPA1 | c.501C>T p.L167= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV55696340; called by muse, mutect2, varscan2
- RPN2 | c.435C>G p.L145= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as COSV52908863; called by muse, varscan2
- RSPH6A | c.1707G>T p.L569= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV55569964, COSV55575298; called by muse, mutect2, varscan2
- SLC35A1 | c.624G>A p.V208= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs1397802346, COSV65780717; called by muse, mutect2, varscan2
- SLC44A4 | c.1731G>A p.A577= | Silent (SNP) | VAF 58/360 reads (16%) | catalogued as rs142009471; called by muse, mutect2, varscan2
- SLC6A15 | c.1296A>T p.L432= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV57029402; called by muse, mutect2, varscan2
- SLCO4C1 | c.339C>T p.L113= | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as COSV60520050; called by muse, varscan2
- SLITRK5 | c.1131G>T p.A377= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs1261174372, COSV61524639; called by muse, mutect2, varscan2
- SPAM1 | c.1422G>A p.E474= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV56147513; called by muse, mutect2, varscan2
- TNMD | c.630C>G p.A210= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV65977774; called by muse, mutect2, varscan2
- TOMM70 | c.795G>T p.T265= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs778126106, COSV52522303, COSV52525557; called by muse, mutect2, varscan2
- TSSK3 | c.495G>C p.L165= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV61983355; called by muse, mutect2, varscan2
- UBE2J1 | c.21G>T p.L7= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV70562270; called by muse, mutect2, varscan2
- USP47 | c.1179C>T p.F393= (on ENST00000399455 / NM_001372095.1; = p.F305= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100360024, COSV60467803; called by muse, mutect2, varscan2
- VPS33A | c.126A>T p.L42= | Silent (SNP) | VAF 53/287 reads (18%) | catalogued as COSV57358792; called by muse, mutect2, varscan2
- VSTM1 | c.399C>T p.T133= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV58076773; called by muse, mutect2, varscan2
- ZNF208 | c.3504C>A p.P1168= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV68112241; called by muse, mutect2, varscan2
- ZNF655 | c.1335C>T p.F445= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs372713595, COSV53160155; called by muse, mutect2, varscan2
- ZNF160 | c.271+799T>G | Intron (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100762417; called by muse, mutect2, varscan2
